Somatic mutation profile of cancer-model specimen HCM-CSHL-0859-C22-85A (3D Organoid, passage 19; aliquot HCM-CSHL-0859-C22-85A-01D-A85L-36), derived from the primary tumor of HCMI case HCM-CSHL-0859-C22, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 62.9 years (22,982 days).
Specimen HCM-CSHL-0859-C22-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 19.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 840c31cf-8669-47c7-9435-e7adddc8027f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0859-C22-10A (Blood Derived Normal), aliquot HCM-CSHL-0859-C22-10A-01D-A85L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa19361e-8bfc-42ee-ae47-242a3871203f

The open-access MAF lists 76 somatic variants for this specimen: 53 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 22, Nonsense Mutation 5, Frame Shift Del 3, Splice Site 1, 5'UTR 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1A | c.4303C>T p.R1435* | Nonsense Mutation (SNP) | VAF 212/212 reads (100%) | catalogued as rs1568470104; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 171/260 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 379/380 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- C4orf50 | c.655G>A p.A219T (on ENST00000324058; = p.A1451T on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 110/331 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.439); catalogued as rs758974747, COSV100135932, COSV60687321; called by muse, mutect2, varscan2
- CMYA5 | c.11779C>T p.R3927W | Missense Mutation (SNP) | VAF 183/277 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs372893220; called by muse, mutect2, varscan2
- CPD | c.11G>T p.G4V | Missense Mutation (SNP) | VAF 224/350 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.202); catalogued as rs781736103, COSV56716979; called by muse, mutect2, varscan2
- FMN2 | c.1407C>G p.H469Q | Missense Mutation (SNP) | VAF 22/650 reads (3%) | SIFT tolerated (0.79); PolyPhen benign (0.006); catalogued as COSV60447306; called by muse, mutect2
- GLB1 | c.1762C>T p.L588F | Missense Mutation (SNP) | VAF 29/212 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56567485; called by muse, mutect2, varscan2
- HCFC1 | c.2584G>A p.V862I | Missense Mutation (SNP) | VAF 395/395 reads (100%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.959); catalogued as rs1057524502, COSV100130176; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HEATR1 | c.3908A>G p.H1303R | Missense Mutation (SNP) | VAF 84/313 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs745448080; called by muse, mutect2, varscan2
- KIF7 | c.556G>A p.V186M | Missense Mutation (SNP) | VAF 91/526 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1354267066; called by muse, mutect2, varscan2
- L3MBTL1 | c.2123G>A p.R708Q (on ENST00000418998 / NM_001377303.1; = p.R618Q on NM_015478.7) | Missense Mutation (SNP) | VAF 192/388 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.864); catalogued as rs867846143, COSV64230102; called by muse, mutect2, varscan2
- MARK1 | c.1537C>T p.R513* | Nonsense Mutation (SNP) | VAF 89/299 reads (30%) | catalogued as COSV65066674; called by muse, mutect2, varscan2
- MB21D2 | c.1299C>G p.S433R | Missense Mutation (SNP) | VAF 111/422 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.034); catalogued as COSV66665194; called by muse, mutect2, varscan2
- MICAL3 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 33/405 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs746149838; called by muse, mutect2
- MOCS3 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 239/470 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs550877609, COSV99724225; called by muse, mutect2, varscan2
- MYH2 | c.3336G>C p.K1112N | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV55433351, COSV99819653; called by muse, mutect2, varscan2
- PRKCG | c.1921G>T p.E641* | Nonsense Mutation (SNP) | VAF 229/504 reads (45%) | catalogued as COSV54730786; called by muse, mutect2, varscan2
- RCC1L | c.56C>A p.P19Q | Missense Mutation (SNP) | VAF 172/716 reads (24%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.224); catalogued as COSV57320223; called by muse, mutect2, varscan2
- ROBO2 | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 96/96 reads (100%) | SIFT tolerated (0.17); PolyPhen benign (0.311); catalogued as rs746238322, COSV59903872; called by muse, mutect2, varscan2
- SDK1 | c.4615G>A p.V1539I | Missense Mutation (SNP) | VAF 168/376 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs374321407; called by muse, mutect2, varscan2
- SENP7 | c.2480+1G>A p.X827_splice | Splice Site (SNP) | VAF 54/84 reads (64%) | catalogued as rs1316113359, COSV100053526; called by muse, mutect2, varscan2
- TBX5 | c.1178T>A p.L393Q | Missense Mutation (SNP) | VAF 136/401 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV59861959; called by muse, mutect2, varscan2
- TTBK1 | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 592/810 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52488911; called by muse, mutect2, varscan2
- ZNF668 | c.952C>T p.R318W | Missense Mutation (SNP) | VAF 387/755 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770364347, COSV100336619, COSV100336986; called by muse, mutect2, varscan2
- ZNF831 | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 114/679 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as rs1481541336; called by muse, varscan2
- BBOX1 | c.773A>G p.D258G | Missense Mutation (SNP) | VAF 88/294 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- BCKDK | c.593T>A p.L198H | Missense Mutation (SNP) | VAF 23/424 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CD5 | c.1273C>A p.Q425K | Missense Mutation (SNP) | VAF 18/404 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.388); called by muse, mutect2
- CTSG | c.342G>C p.L114= | Splice Region (SNP) | VAF 102/328 reads (31%) | called by muse, mutect2, varscan2
- FFAR2 | c.446A>G p.Y149C | Missense Mutation (SNP) | VAF 228/461 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FSIP2 | c.18745A>C p.I6249L | Missense Mutation (SNP) | VAF 131/306 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- GPRC5B | c.283C>A p.L95I | Missense Mutation (SNP) | VAF 39/702 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.015); called by muse, mutect2
- GRIP1 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 85/280 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- HSPA4L | c.1085T>A p.I362K | Missense Mutation (SNP) | VAF 146/219 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- IGSF3 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 99/312 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- LRFN5 | c.410T>C p.L137S | Missense Mutation (SNP) | VAF 24/528 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.03); called by muse, mutect2
- MTF2 | c.1570G>C p.D524H | Missense Mutation (SNP) | VAF 81/309 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.601); called by muse, mutect2
- MYOM2 | c.1797_1802del p.T600_S601del | In Frame Del (DEL) | VAF 203/206 reads (99%) | called by mutect2, pindel, varscan2
- NDUFS6 | c.188T>C p.V63A | Missense Mutation (SNP) | VAF 121/368 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- OR52E2 | c.587T>A p.I196N | Missense Mutation (SNP) | VAF 66/372 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- PTPRQ | c.4129A>T p.T1377S (on ENST00000616559; = p.T1335S on NM_001145026.2) | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PZP | c.3059G>T p.R1020I | Missense Mutation (SNP) | VAF 64/213 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RBFA | c.218A>T p.K73M | Missense Mutation (SNP) | VAF 157/157 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- SESN2 | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 91/211 reads (43%) | called by muse, mutect2, varscan2
- SIK2 | c.86del p.G29Afs*6 | Frame Shift Del (DEL) | VAF 489/682 reads (72%) | called by mutect2, pindel, varscan2
- SPDYE2 | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 70/688 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- TCP11 | c.607A>C p.K203Q (on ENST00000512012; = p.K141Q on NM_018679.5) | Missense Mutation (SNP) | VAF 32/689 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2
- TOP2A | c.2764G>T p.E922* | Nonsense Mutation (SNP) | VAF 200/309 reads (65%) | called by mutect2, varscan2
- UNC93B1 | c.163del p.R55Afs*32 | Frame Shift Del (DEL) | VAF 146/585 reads (25%) | called by mutect2, pindel, varscan2
- USP27X | c.806G>A p.R269K | Missense Mutation (SNP) | VAF 21/396 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.458); called by muse, mutect2
- ZDBF2 | c.4086_4087del p.Y1362* | Frame Shift Del (DEL) | VAF 166/472 reads (35%) | called by pindel, varscan2
- ZNF790 | c.1321G>C p.E441Q | Missense Mutation (SNP) | VAF 78/502 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- A1BG | c.1152G>T p.G384= | Silent (SNP) | VAF 356/681 reads (52%) | catalogued as rs1174452912, COSV54051087; called by muse, mutect2, varscan2
- ABCA12 | c.4950C>T p.Y1650= (on ENST00000272895 / NM_173076.3; = p.Y1332= on NM_015657.3) | Silent (SNP) | VAF 151/314 reads (48%) | catalogued as rs371166748, CM1511268, COSV55948013; called by muse, mutect2, varscan2
- AHNAK2 | c.1581G>A p.L527= | Silent (SNP) | VAF 34/746 reads (5%) | called by muse, mutect2
- CEP97 | c.442C>T p.L148= | Silent (SNP) | VAF 68/209 reads (33%) | called by muse, mutect2, varscan2
- CMPK2 | c.867C>T p.G289= | Silent (SNP) | VAF 227/503 reads (45%) | catalogued as rs1401947028; called by muse, mutect2, varscan2
- COL5A1 | c.4629T>C p.G1543= | Silent (SNP) | VAF 232/232 reads (100%) | called by muse, mutect2, varscan2
- DAB2IP | c.3351C>T p.H1117= (on ENST00000408936; = p.H1089= on NM_032552.3) | Silent (SNP) | VAF 201/202 reads (100%) | catalogued as rs376673781; called by muse, mutect2, varscan2
- FSIP2 | c.14565T>A p.I4855= | Silent (SNP) | VAF 94/191 reads (49%) | called by muse, mutect2, varscan2
- GPRC5B | c.282C>A p.G94= | Silent (SNP) | VAF 40/698 reads (6%) | called by muse, mutect2
- GRIP1 | c.66C>T p.P22= | Silent (SNP) | VAF 86/281 reads (31%) | called by muse, mutect2, varscan2
- HS3ST4 | c.282C>A p.P94= | Silent (SNP) | VAF 309/678 reads (46%) | called by muse, mutect2, varscan2
- IGFBP5 | c.531C>T p.I177= | Silent (SNP) | VAF 61/465 reads (13%) | called by muse, mutect2, varscan2
- LPP | c.603C>G p.P201= | Silent (SNP) | VAF 181/570 reads (32%) | called by muse, mutect2, varscan2
- LY75 | c.3954T>C p.Y1318= | Silent (SNP) | VAF 99/234 reads (42%) | catalogued as rs139342011; called by muse, mutect2, varscan2
- OGA | c.2010A>G p.Q670= | Silent (SNP) | VAF 133/287 reads (46%) | catalogued as rs768126488, COSV63380868; called by muse, mutect2, varscan2
- PLEKHB2 | c.807G>A p.P269= | Silent (SNP) | VAF 215/479 reads (45%) | catalogued as rs548216063; called by muse, mutect2, varscan2
- RNF43 | c.1215G>A p.L405= | Silent (SNP) | VAF 354/354 reads (100%) | catalogued as rs1448040339; called by muse, mutect2, varscan2
- RYR2 | c.9564T>C p.S3188= | Silent (SNP) | VAF 43/200 reads (22%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.774C>T p.R258= | Silent (SNP) | VAF 368/738 reads (50%) | catalogued as COSV64525986, COSV64527767; called by muse, varscan2
- TNS3 | c.2709C>T p.I903= | Silent (SNP) | VAF 124/562 reads (22%) | catalogued as rs577707096; called by muse, mutect2, varscan2
- ZBTB40 | c.189A>T p.A63= | Silent (SNP) | VAF 114/255 reads (45%) | called by muse, mutect2, varscan2
- ZFP28 | c.12G>A p.A4= | Silent (SNP) | VAF 230/372 reads (62%) | called by mutect2, varscan2
- ELL2 | c.-94G>T | 5'UTR (SNP) | VAF 250/252 reads (99%) | called by muse, varscan2
